Somatic mutation profile of tumor specimen TCGA-B6-A0X5-01A (aliquot TCGA-B6-A0X5-01A-21D-A10G-09) from TCGA case TCGA-B6-A0X5, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 61.3 years (22,380 days).
Specimen TCGA-B6-A0X5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bef1a04a-892c-42dc-9dbb-963cb253925e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0X5-10A (Blood Derived Normal), aliquot TCGA-B6-A0X5-10A-01D-A10G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a58ae990-79f5-4c3b-9cf4-5e54207eb495

The open-access MAF lists 41 somatic variants for this specimen: 31 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 25, Silent 10, Frame Shift Del 2, Frame Shift Ins 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 23/58 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCG2 | c.624C>A p.F208L | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52947215; called by muse, mutect2
- ALOXE3 | c.1588T>G p.Y530D | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59076505; called by muse, mutect2, varscan2
- AMHR2 | c.717G>T p.Q239H | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.981); catalogued as rs949006402, COSV57686199; called by muse, mutect2, varscan2
- AP3B1 | c.356C>G p.T119S | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.19); catalogued as COSV54887086; called by muse, mutect2, varscan2
- ATP11C | c.2408G>T p.R803I | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV59565472, COSV59567788; called by muse, mutect2, varscan2
- BHMT | c.215A>C p.Q72P | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57154909; called by muse, mutect2, varscan2
- CELA1 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374315048; called by muse, mutect2, varscan2
- CENPL | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 19/65 reads (29%) | catalogued as rs994018186, COSV61891896; called by muse, mutect2, varscan2
- FAT1 | c.8013C>A p.F2671L | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV71674897; called by muse, mutect2, varscan2
- IFT22 | c.460C>G p.P154A | Missense Mutation (SNP) | VAF 5/112 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.174); catalogued as COSV100190147, COSV59526959; called by muse, mutect2
- KHSRP | c.1496T>C p.L499P | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV67919961; called by muse, mutect2, varscan2
- MAGEC2 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.77); catalogued as COSV56000249; called by muse, mutect2, varscan2
- MYH14 | c.5380C>T p.R1794C | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751422907, COSV51819684; called by muse, mutect2, varscan2
- MYH3 | c.4881G>T p.E1627D | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56866932; called by muse, mutect2
- NAPA | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as rs1329160231, COSV54550795; called by muse, mutect2, varscan2
- NEMF | c.2301G>T p.M767I | Missense Mutation (SNP) | VAF 89/200 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV53593020; called by muse, mutect2, varscan2
- PADI4 | c.719T>C p.V240A | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.5); PolyPhen benign (0.067); catalogued as COSV64924356; called by muse, mutect2, varscan2
- PCDHB5 | c.2262G>T p.L754F | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); catalogued as COSV50657170; called by muse, mutect2, varscan2
- PDE1C | c.164A>G p.E55G | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58518760; called by muse, mutect2
- RGS12 | c.162T>G p.D54E | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT tolerated (0.13); PolyPhen benign (0.138); catalogued as COSV60907075; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 19/52 reads (37%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- SATB1 | c.2143G>A p.D715N | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as COSV58669715; called by muse, mutect2, varscan2
- SMARCA4 | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as rs751542188, COSV60798215; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMOC2 | c.1068C>A p.F356L (on ENST00000356284 / NM_001166412.2; = p.F367L on NM_022138.3) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1318827032, COSV62437591, COSV62440120; called by muse, mutect2, varscan2
- SYVN1 | c.1339G>C p.E447Q (on ENST00000377190 / NM_172230.3; = p.E446Q on NM_032431.3) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.62); PolyPhen benign (0.031); catalogued as COSV53695972; called by muse, mutect2, varscan2
- WWP1 | c.2395-2A>G p.X799_splice | Splice Site (SNP) | VAF 9/221 reads (4%) | catalogued as COSV55356536, COSV99617456; called by muse, mutect2
- XPO7 | c.1587G>T p.Q529H | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV53016861; called by muse, mutect2, varscan2
- PHF20L1 | c.1573dup p.A525Gfs*23 | Frame Shift Ins (INS) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- SLC13A5 | c.1505dup p.M503Hfs*22 | Frame Shift Ins (INS) | VAF 20/47 reads (43%) | called by mutect2, pindel, varscan2
- TAS2R16 | c.264del p.F88Lfs*8 | Frame Shift Del (DEL) | VAF 30/92 reads (33%) | called by mutect2, pindel, varscan2
- COL5A3 | c.4339C>T p.L1447= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV53413743; called by muse, mutect2, varscan2
- DENND2C | c.279T>C p.S93= | Silent (SNP) | VAF 17/153 reads (11%) | catalogued as COSV67922527; called by muse, mutect2, varscan2
- DENND4B | c.1455G>A p.P485= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs140778233, COSV63410300; called by muse, mutect2, varscan2
- KCND3 | c.252C>T p.F84= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as rs765352071, COSV56174311; called by muse, mutect2, varscan2
- MAT2A | c.651A>G p.E217= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as COSV52089104; called by muse, mutect2, varscan2
- MYLK | c.156C>T p.F52= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs200095645, COSV60604762; ClinVar: likely benign; called by muse, mutect2, varscan2
- NHLRC3 | c.570G>A p.L190= | Silent (SNP) | VAF 84/108 reads (78%) | catalogued as COSV61488457; called by muse, mutect2, varscan2
- NRXN3 | c.1863G>A p.S621= (on ENST00000557594 / NM_001272020.2; = p.S1045= on NM_004796.6) | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as rs754484520, COSV55328444; called by muse, mutect2, varscan2
- SPP2 | c.153G>T p.V51= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as COSV51445928; called by muse, mutect2, varscan2
- TTN | c.78711T>C p.N26237= (on ENST00000591111; = p.N18813= on NM_003319.4) | Silent (SNP) | VAF 41/86 reads (48%) | catalogued as COSV60167858; called by muse, mutect2, varscan2
